CCDI case PBBHYD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b72d2dfe-5bcd-4977-b27a-90656d1b1b4b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 1.9 years (690 days).

Biospecimens (3 samples)
- Sample 0D9W64: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9W6A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9W6B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
